Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A7NM, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A7NM-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

PART 1: LYMPH NODE, RIGHT PELVIC, DISSECTION -

- A. METASTATIC PROSTATE ADENOCARCINOMA IDENTIFIED IN ONE OF SIXTEEN LYMPH NODES (1/16).
- B. NO EXTRANODAL EXTENSION IDENTIFIED.

PART 2: LYMPH NODE, LEFT PELVIC, DISSECTION -

- A. METASTATIC PROSTATE ADENOCARCINOMA IDENTIFIED TWO OF THIRTEEN LYMPH NODES (2/13).
- B. NO EXTRANODAL EXTENSION IDENTIFIED.

PART 3: PROSTATE, BILATERAL SEMINAL VESICLES AND VASA DEFERENTIA, RADICAL PROSTATECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED PROSTATIC ADENOCARCINOMA, MIXED ACINAR AND DUCTAL TYPE, GLEASON SCORE 4+5=9.
- B. CARCINOMA INVOLVED BOTH RIGHT AND LEFT LOBES WITH THE GREATEST NODULAR DIAMETER OF 2.5 CM.
- C. CARCINOMA INVOLVES APPROXIMATELY 40% OF THE EXAMINED PROSTATIC VOLUME.
- D. MULTIFOCAL ESTABLISHED EXTRACAPSULAR EXTENSION IS IDENTIFIED IN THE FOLLOWING REGIONS OF THE PROSTATE :
- a. ANTERIOR LEFT MID (3T)
- b. POSTERIOR RIGHT APEX (3J, 3V)
- c. POSTERIOR RIGHT MID (3L, 3W)
- d. POSTERIOR RIGHT BASE (3X)
- e. POSTERIOR LEFT APEX (3Y)
- f. POSTERIOR LEFT MID (3Z)
- g. POSTERIOR LEFT BASE (3AA)
- E. TUMOR INVADERS BILATERAL SEMINAL VESICLES.
- F. ALL SURGICAL MARGINS OF RESECTION ARE FREE OF CARCINOMA.
- G. EXTENSIVE PERINEURAL INVASION IS IDENTIFIED.
- H. LYMPHOVASCULAR INVASION IS IDENTIFIED.
- I. MULTIFOCAL HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN) IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE (AJCC 7TH EDITION): pT3b N1 MX.
- K. TNM HISTOLOGIC GRADE: G3-4.
- L. BACKGROUND PROSTATIC PARENCHYMA WITH MODERATE CHRONIC INFLAMMATION AND FOCAL ATROPHIC FEATURES.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 7.02
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS Ductal adenocarcinoma
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	5
GLEASON SUM SCORE:	9
GLEASON 4/5 PERCENTAGE:	95%
WEIGHT OF PROSTATE:	64.10gm
TUMOR SIZE:	Maximum dimension: 2.5 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	> 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Multifocal
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	Yes
SEMINAL VESICLE INVASION:	Yes
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	29
LYMPH NODES POSITIVE:	3
EXTRANODAL EXTENSION:	No
SIZE OF NODAL METASTASIS:	0.5mm
T STAGE, PATHOLOGIC:	pT3b
N STAGE, PATHOLOGIC:	pN1
M STAGE, PATHOLOGIC:	PMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Adenocarcinoma, acinar + ductal
8/40/13 8500/13
Code to highest 8500/13
path
Adenocarcinoma NOS + Adenocarcinoma
8/40/13
ductal
8500/13
Code to highest 8500/13
Site Prostate NOS 061.9
9/24/13

Source: NCI Genomic Data Commons file c58e937a-9c10-49bc-9249-dd4c6dd9839f (TCGA-EJ-A7NM.D7D49539-80E3-4A37-BEEB-FA75951947F8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).